Somatic mutation profile of tumor specimen 0DQS06 from CCDI case PBCFIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.2 years (5,174 days).
Specimen 0DQS06: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c74d2b4e-e4d9-4800-8e8c-920c6a94dfa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f6e364-e467-4dd7-87d3-8a6cae0ade5d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 250/1300 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 205/1186 reads (17%) | catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 205/1196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- PNPLA3 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 99/673 reads (15%) | catalogued as rs144830716, COSV53377228; called by muse, mutect2, varscan2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 26/907 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC2A8 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 20/638 reads (3%) | called by muse, mutect2
